Somatic mutation profile of tumor specimen 1105246 (aliquot 7316UP-213-1105246) from CPTAC case C243048, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Tumor grade: G4.
Specimen 1105246: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be5144c4-46f9-42c9-853d-b4113a6cd455.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105206 (Blood Derived Normal), aliquot 7316UP-1282-1105206; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ae37ab8-18f1-4001-9e47-f842b0136238

The open-access MAF lists 43 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 8, Intron 4, Nonsense Mutation 2, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 66/246 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PYGL | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 23/345 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs113993986, CM078414; ClinVar: pathogenic; called by muse, mutect2
- C1orf94 | c.577G>A p.V193I (on ENST00000488417 / NM_001134734.2; = p.V3I on NM_032884.5) | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs773093561; called by muse, mutect2, varscan2
- COLEC10 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV100250951, COSV60522639; called by muse, mutect2
- CRYBG1 | c.2881G>A p.V961M | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.213); catalogued as rs200844028, COSV64812584; called by muse, mutect2
- GBA2 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62306518; called by muse, varscan2
- GBA2 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs756503362; called by muse, mutect2, varscan2
- KRTAP4-7 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs554015981; called by muse, mutect2, varscan2
- LCOR | c.3785G>A p.R1262Q | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as rs201744063; called by muse, mutect2, varscan2
- MCM8 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1365419029, COSV99495753; called by muse, mutect2
- NME8 | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 37/421 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.886); catalogued as rs779582375; called by muse, mutect2
- TMEM8B | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs200479301; called by muse, mutect2, varscan2
- TRIM49B | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 27/312 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs754589516, COSV60319963, COSV99081987; called by muse, mutect2
- VWDE | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 39/315 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51725806; called by muse, mutect2, varscan2
- ATP8B1 | c.571T>C p.W191R | Missense Mutation (SNP) | VAF 68/383 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP61 | c.2891A>G p.D964G | Missense Mutation (SNP) | VAF 24/371 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- CSMD2 | c.3737G>A p.G1246D | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GAREM1 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 40/818 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- GAREM1 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 32/804 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- GBA2 | c.1523G>C p.R508T | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, varscan2
- IRAG1 | c.19A>G p.S7G | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.313); called by muse, mutect2
- ITGA7 | c.1202T>C p.V401A (on ENST00000555728; = p.V357A on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PLAGL1 | c.84G>T p.R28S | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.062); called by muse, mutect2
- PPP1R3F | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.8); PolyPhen probably damaging (0.914); called by muse, mutect2
- PRSS16 | c.614C>A p.S205* | Nonsense Mutation (SNP) | VAF 45/226 reads (20%) | called by muse, mutect2, varscan2
- PTCHD1 | c.525C>A p.Y175* | Nonsense Mutation (SNP) | VAF 21/340 reads (6%) | called by muse, mutect2
- TP53 | c.656_657dup p.Y220Pfs*28 | Frame Shift Ins (INS) | VAF 271/514 reads (53%) | called by mutect2, pindel, varscan2
- UTRN | c.5866A>G p.K1956E | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR70 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF653 | c.733C>G p.P245A | Missense Mutation (SNP) | VAF 160/528 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- DKKL1 | c.573C>T p.S191= | Silent (SNP) | VAF 40/304 reads (13%) | catalogued as rs375202437, COSV55561777; called by muse, mutect2, varscan2
- EHD4 | c.762C>G p.R254= | Silent (SNP) | VAF 43/179 reads (24%) | called by muse, mutect2, varscan2
- MYO15A | c.2514G>A p.S838= | Silent (SNP) | VAF 33/246 reads (13%) | catalogued as rs953132094; called by muse, mutect2, varscan2
- NEK10 | c.2727G>T p.S909= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as COSV55355950; called by muse, mutect2, varscan2
- OR5AR1 | c.669T>A p.V223= | Silent (SNP) | VAF 14/240 reads (6%) | called by muse, mutect2
- PNISR | c.2061A>G p.E687= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as rs1476804612; called by muse, mutect2, varscan2
- SYDE1 | c.843G>A p.A281= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs1343918919, COSV54621634; called by muse, mutect2, varscan2
- TLN1 | c.6375G>A p.V2125= | Silent (SNP) | VAF 34/322 reads (11%) | catalogued as COSV59205102; called by muse, mutect2, varscan2
- CHD9 | c.1453-1155del | Intron (DEL) | VAF 6/74 reads (8%) | called by mutect2, varscan2
- EYS | c.1767-6584C>T | Intron (SNP) | VAF 97/304 reads (32%) | catalogued as rs753104022, COSV101005079; called by mutect2, varscan2
- INO80E | c.82-30G>A | Intron (SNP) | VAF 14/318 reads (4%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34159745 G>A | 5'Flank (SNP) | VAF 117/414 reads (28%) | catalogued as rs796298062; called by muse, mutect2, varscan2
- SLC25A13 | c.1019-15A>G | Intron (SNP) | VAF 126/311 reads (41%) | called by muse, mutect2, varscan2
